Somatic mutation profile of tumor specimen TCGA-ZL-A9V6-01A (aliquot TCGA-ZL-A9V6-01A-11D-A428-09) from TCGA case TCGA-ZL-A9V6, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 61.5 years (22,447 days).
Specimen TCGA-ZL-A9V6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9398eea5-ed22-436f-a83c-b104f7d95a8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZL-A9V6-10A (Blood Derived Normal), aliquot TCGA-ZL-A9V6-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14df2598-ab60-4999-90fe-4e1211ba82ba

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 144/498 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HRAS | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54236714, COSV54237107; called by muse, mutect2, varscan2
- ABCA7 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs148324257, COSV54027881; called by muse, mutect2, varscan2
- CHRNA7 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs199698778; called by muse, mutect2, varscan2
- CTSG | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as rs1192581133; called by muse, mutect2, varscan2
- DEFB112 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.92); PolyPhen benign (0.067); catalogued as rs760015661; called by muse, mutect2, varscan2
- IGF2R | c.3974G>A p.R1325H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751103307; called by muse, mutect2, varscan2
- IGHV3-21 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); catalogued as rs782560580; called by muse, mutect2, varscan2
- PYGM | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1314271741; called by muse, mutect2, varscan2
- TENM3 | c.5282A>G p.N1761S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1365358466; called by muse, mutect2
- ZBTB10 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1398454624; called by muse, mutect2, varscan2
- ADAM18 | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- MIB1 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NRK | c.2327T>C p.I776T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PEX10 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, varscan2
- SERPINE2 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS16 | c.1692G>T p.K564N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- YME1L1 | c.359A>T p.D120V (on ENST00000326799 / NM_139312.3; = p.D63V on NM_014263.4) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- PAOX | c.363C>T p.S121= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs527822098; called by muse, mutect2, varscan2
- WDR17 | c.2067A>C p.V689= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99708430; called by muse, mutect2, varscan2
